Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7104, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7104-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) PARTIAL PHARYNGECTOMY, TOTAL GLOSSECTOMY, LEFT MANDIBULECTOMY AND LEFT NECK DISSECTION:

INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, KERATINIZING.
THE TUMOR MEASURES 11.0 MM IN THICKNESS.
Margins free of tumor.
PERINEURAL INVASION PRESENT.
VASCULAR/LYMPHATIC INVASION PRESENT.
METASTATIC SQUAMOUS CELL CARCINOMA IN 8 OF 30 LYMPH NODES (LEVEL I 2/4, LEVEL II 1/1, LEVEL III 4/13, LEVEL 0/4 AND LEVEL 5 1/8).
MULTIPLE METASTATIC SQUAMOUS CELL CARCINOMA IN FIBROADIPOSE TISSUE AND SKELETAL MUSCLE INVOLVING ALL LEVELS. (SEE COMMENT)
salivary gland with chronic inflammation, no tumor present.

Entire report and diagnosis completed by: [REDACTED]

COMMENT

Multiple tumor nodules in fibroadipose tissue most likely represent entirely replaced lymph nodes.

GROSS DESCRIPTION

(A) NASAL PHARYNGECTOMY, PARTIAL PHARYNGECTOMY, LEFT NECK DISSECTION, TOTAL GLOSSECTOMY, LEFT MANDIBULECTOMY - A 17.5 x 10.4 x 6.2 cm specimen consisting of tongue (6.1 x 4.6 x 3.7 cm), left pharynx (3.5 x 2.6 cm), left mandible (8.5 x 5.2 x 1.8 cm), and left neck contents (15.0 x 7.7 x 1.7 cm). According to the surgeon, the left neck contents corresponds to levels I-V.

Present in the area of the left tonsillar bed and spreading to cover both the left pharynx and left posterior lateral aspect of the tongue is a ulcerated tan-red lesion (2.5 x 2.3 cm, depth 0.8 cm). Sectioning through this lesion reveals gray-tan rubbery apparent tumor which has a thickness of 0.8 cm.

The anterior tongue has a gray-tan rubbery fairly well circumscribed mass (1.5 x 1.3 x 0.8 cm).

The submucosal tissue of the midportion of the tongue, between the two ill-defined lesions. is gray-tan and rubbery.

Identified within the level I neck contents is a gray-white poorly circumscribed rubbery mass (1.5 x 1.5 x 1.0 cm). In addition, a fibrotic submandibular gland (1.6 x 1.3 x 1.2 cm) is also present within the level I contents. Four possible level I lymph nodes (ranging from 0.3 cm to 0.9 x 0.8 x 0.8 cm) are identified. within the levels II contents is a rubbery gray-tan

[page 2 of 2]
poorly circumscribed mass (2.0 x 1.5 x 0.9 cm). Twelve possible level III lymph nodes (ranging from 0.1 cm to 1.3 x 0.7 x 0.7 cm) are present. Four possible level IV lymph nodes (ranging from 0.1 cm to 0.5 x 0.4 x 0.4 cm) are present. Twelve possible level V lymph nodes (ranging from 0.1 cm to 0.4 x 0.3 x 0.2 cm) are identified.

INK CODE: Black - soft tissue margin of resection.

SECTION CODE: A1-A17, mucosal margins, beginning at most anterior aspect of specimen and submitted clockwise, en face (See frozen section sheet); A18, mass, tip of tongue, for frozen section examination; A19, mass, level I neck contents, for frozen section examination; A20-A24, left tonsillar/pharyngeal mass, representative sections; A25, A26, mass, tip of tongue; A27-A29, firm, indurated area in mid tongue; A30, A31, soft tissue, level I; A32, submandibular gland, representative sections; A33, level I, three possible lymph nodes; A34, level I, one lymph node, serially sectioned; A35, A36, level II, soft tissue mass, representative sections; A37, level III, five possible lymph nodes; A38, level III, five possible lymph nodes; A39, A40, level III, one bisected lymph node per cassette; A41, level IV, four possible lymph nodes; A42, level V, five possible lymph nodes; A43, level V, four possible lymph nodes; A44, level V, three possible lymph nodes.

*FS/DX: MUCOSAL MARGINS WITH DYSPLASIA IN A9; SQUAMOUS CARCINOMA.

SNOMED CODES

M-80703 M-80706 T-53000 T-55000 T-C4200 T-D166Y

Source: NCI Genomic Data Commons file 69f783fe-0166-4cf3-b8cd-69ecdd24655f (TCGA-CV-7104.CA4045BB-4BEA-4CBD-B281-5B380C3DFFA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).